Somatic mutation profile of tumor specimen C3L-06539-54 (aliquot CPT0357830002) from CPTAC case C3L-06539, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 73.0 years (26,656 days).
Specimen C3L-06539-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20ed1fac-6280-4945-b3fa-aa47407f185d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06539-51 (Buccal Cell Normal), aliquot CPT0357800003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3856cc7d-cd4b-4995-aa88-325677485133

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM171A1 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1425442305, COSV65315873; called by muse, mutect2
- STAG2 | c.385+2dup p.X129_splice | Splice Site (INS) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- CILP2 | c.3180C>T p.G1060= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as rs755652073; called by muse, mutect2, varscan2
